Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-5330, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-5330-01A (Primary Tumor).

[page 1 of 3]
Specimen(s) Received

1. Nck: RT. perifacial node
2. Neck: contents right neck - reg
3. Neck: right hemiglossectomy (short stitch = anterior/ long stitch = medial) - reg
4. Soft-Tissue: deep margin tongue

Diagnosis

1. Right perifacial node:
- One lymph node, negative for malignancy (0/1).
2. Right neck, dissection:
- Metastatic squamous cell carcinoma involving three of forty-four lymph nodes (3/44).
- a. All involved nodes are level III.
- b. Largest node involved: 1.8 cm.
- c. Extracapsular extension present.
- Submandibular gland with mild chronic inflammation, negative for malignancy.
3. Right tongue, hemiglossectomy:
- Squamous cell carcinoma, poorly differentiated.
- a. Maximal tumour dimension: 4.0 cm.
- b. Tumour thickness: 2.3 cm.
- c. Perineural invasion present.
- d. Invasive carcinoma seen focally very close (0.2 cm) to the medial margin.
- e. Severe squamous dysplasia/carcinoma in-situ (CIS) seen focally close (0.3 cm) to the inferior/lateral margin.
- f. All other margins negative for malignancy (> 0.5 cm).
4. Deep margin tongue:
- Negative for malignancy.

Synoptic Data

Specimen Type:	Resection: Right hemiglossectomy
Tumor Site:	Tongue
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 4.0 cm
	Tumor thickness: 2.3 cm

[page 2 of 3]
Histologic Grade: G3: Poorly differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent
Perineural Invasion: Present
Additional Pathologic Findings: Carcinoma in situ
Margins: Margins uninvolved by tumor
Margins uninvolved by tumor - Distance of tumor from closest margin: 0.2 cm
Margins: medial
Pathologic Staging (pTNM): pT3: Tumor or lip or oral cavity more than 4 cm in greatest dimension
pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6 cm in greatest dimension for all aerodigestive sites except nasopharynx
Number of regional lymph nodes examined: 44
Number of regional lymph nodes involved: 3
Extra-capsular extension of nodal tumor: Present
pMX: Distant metastasis cannot be assessed

Gross Description

1. The specimen is labeled with the patient's name and as "NCK: RT perifacial node". It consists of a lymph node that measures 0.9 x 0.8 x 0.5 cm.

1A bisected and submitted in toto

2. The specimen labeled with the patient's name and as "neck: Contents right neck -- reg" consists of an unoriented neck dissection with overall dimensions of 13.5 cm SI x 6.0 cm AP x 2.5 cm ML. There is no suture orientation; the specimen grossly appears to include right levels I, II, III and IV, as approximated utilizing the position of the submandibular gland. The internal jugular vein and the sternocleidomastoid muscle are absent. The submandibular gland measures 3.5 x 2.2 x 2.0 cm and is unremarkable. Multiple lymph nodes ranging from 0.2 to 1.8 cm are identified in multiple levels.

Representative sections are submitted.

2A submandibular gland

2B level I, two lymph nodes

2C level II, two lymph nodes

2D-2F level III, one bisected lymph node per block

2G level III, two lymph nodes

2H level III, three lymph nodes

2I level III, four lymph nodes

2J level III, five lymph nodes

2K level IV, one bisected lymph node

2L level IV, three lymph nodes

2M-2N level IV, four lymph nodes per block

2O-2P level IV, five lymph nodes per block

3. The specimen is labeled the patient's name and as "neck: Right hemiglossectomy (short stitch = anterior/long stitch = medial)- reg". It consists of a portion of right tongue measuring 6.5 cm AP x 3.4 cm SI x 3.5 cm ML. There is short anterior, long medial suture orientation. There is a firm tumor involving the lateral and dorsal surfaces of the tongue. The tumor measures 4.0 cm AP x 3.7 cm SI x 2.3 cm ML. The tumor is pale and well delineated, and ulcerates the lateral mucosal tongue surface. It grossly appears to involve the lateral mucosal margin, is 0.4 cm from the medial margin, appears to involve the dorsal mucosal margin, is 0.2 cm from the inferior margin, 0.8 cm from the anterior margin, and 0.7 from the posterior margin. The remaining tongue mucosa has white plaques extending postero-superiorly from the tumor. These plaques measure 1.0 cm AP x 1.0 cm SI in aggregate. The surgical margins are painted with silver nitrate; superior margins are over coated with green dye. The tumor (four pieces) and normal tissue are sampled for tissue banking.

Representative sections are submitted.

3A anterior margin, perpendicular section

[page 3 of 3]
[REDACTED]

- 3B-3I tumor sampled from anterior to posterior, each pair of blocks a full thickness section, bisected, with the superior aspect in the first of each pair and the inferior aspect in the second of each pair
- 3J mucosal plaques postero-superior to tumor
- 3K posterior margin, perpendicular section

4. The specimen is labeled with the patient's name and as "soft tissue: Deep margin tongue QS". It consists of a fragment of tissue measuring 1.1 x 1.0 x 0.9 cm. The specimen is bisected and submitted in toto for frozen section. The specimen is subsequently submitted in toto for research.

4A frozen section control: submitted in toto for research

[REDACTED]

Quick Section Diagnosis

4A. Deep tongue margin: negative for malignancy.

[REDACTED]

Source: NCI Genomic Data Commons file c460750a-c03c-4e5c-9e36-443efac816f1 (TCGA-CQ-5330.3DF8C3E2-3A3B-4AE2-88B5-A565AC89B985.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).